MMRF case MMRF_1345 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/568c22f1-425b-4f99-811e-71554cfc7218

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.8 years (22,223 days); ISS stage: I; Days to last known disease status: 1,443 days (4.0 years); Days to last follow up: 1,443 days (4.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days; Days to treatment end: 73 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 219 days; Days to treatment end: 219 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 219 days; Days to treatment end: 219 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 911 days (2.5 years); Days to treatment end: 1,086 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 911 days (2.5 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,086 days (3.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 1.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.8 mg/dL; Immunoglobulin G 23.2 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.79 g/L; Beta 2 Microglobulin 2.09 µg/mL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Glucose 5.56 mmol/L.
- Day 73 (ECOG 1): M Protein 0.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 5.77 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 4.51 mmol/L.
- Day 155 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.794 mg/dL; Immunoglobulin G 8.82 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.06 mmol/L.
- Day 253 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.958 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.703 mg/dL; Immunoglobulin G 8.75 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 4.88 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 7.1 mmol/L.
- Day 316 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 6 mmol/L.
- Day 437 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.94 g/L; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 5.94 mmol/L.
- Day 498 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.87 mg/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 1.81 g/L; Immunoglobulin M 1.62 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 5.34 mmol/L.
- Day 589 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 20 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.87 g/L; Beta 2 Microglobulin 2.27 µg/mL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.55 mmol/L; Albumin 46 g/L; Total Protein 8.5 g/dL; Glucose 4.29 mmol/L.
- Day 708 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 3.85 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 6.44 mmol/L.
- Day 806 (ECOG 1): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 1.64 µg/mL; Hemoglobin 6.45 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 4.76 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 4.57 mmol/L.
- Day 911 (ECOG 1): M Protein 1.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.2 mg/dL; Immunoglobulin G 26.3 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 4.59 mmol/L; Leukocytes 12.3 ×10⁹/L; Absolute Neutrophil 7.87 ×10⁹/L; Platelets 400 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 7.8 g/dL; Glucose 6.05 mmol/L.
- Day 981 (ECOG 1): M Protein 0.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.9 g/L; Hemoglobin 5.58 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 7.6 g/dL; Glucose 6.77 mmol/L.
- Day 1,086 (ECOG 0): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 48 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.5 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.12 mmol/L.
- Day 1,156 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 8.66 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.3 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.
- Day 1,254 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.965 mg/dL; Immunoglobulin G 9.17 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 4.43 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5.78 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.55 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 6.49 mmol/L.
- Day 1,338 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 9.54 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 4.07 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 6.11 mmol/L.
- Day 1,443 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 5.98 g/L; Immunoglobulin A 1.35 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.04 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 6.49 mmol/L.

Other clinical attributes
- Day -6: Weight: 71 kg; Height: 167 cm.

Biospecimens (2 samples)
- Sample MMRF_1345_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
- Sample MMRF_1345_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 911 days (2.5 years).
